Gene-level copy-number profile of tumor specimen ALCH-B414-TTP1-A from ALCHEMIST case ALCH-B414, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.3 years (26,757 days).
Specimen ALCH-B414-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3fd5ed9a-009d-4a29-8271-3e685d90b9e0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B414-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/321c13d0-ca0b-40f9-8681-7917babab8b7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 81; copy number 1: 3,583; copy number 2: 55,155; copy number 3: 71; copy number 4: 4; copy number 5: 1; copy number 11: 1; copy number 13: 1.

Homozygous deletions (total copy number 0; autosomes only): 55 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:212,824,027–212,847,649, 2 genes: AC104333.3, SPATA45.
- chr2:44,932,320–44,968,762, 10 genes: AC012354.2, AC012354.7, AC012354.5, AC012354.8, AC012354.4, AC012354.3, AC012354.6, SIX3-AS1, SIX3, AC012354.1.
- chr7:983,181–989,640, 1 gene: CYP2W1.
- chr7:1,464,497–1,467,522, 1 gene: AC102953.2.
- chr8:142,611,049–142,621,064, 2 genes: ARC, AP006547.1.
- chr8:144,502,973–144,529,132, 7 genes (within-gene range 0–2): GPT, MFSD3, RECQL4, AC084125.4, LRRC14, LRRC24, C8orf82.
- chr10:102,085,476–102,090,062, 2 genes: AL500527.1, AL500527.2.
- chr11:1,828,307–1,841,680, 2 genes: SYT8, TNNI2.
- chr11:66,848,417–66,958,386, 4 genes (within-gene range 0–2): PC, LRFN4, RNU7-23P, MIR3163.
- chr12:124,529,722–124,542,873, 3 genes (within-gene range 0–2): AC073592.7, AC073592.3, AC073592.9.
- chr14:103,912,288–103,928,269, 1 gene: ATP5MPL.
- chr15:41,774,434–41,894,053, 8 genes (within-gene range 0–2): MAPKBP1, AC020659.2, JMJD7, JMJD7-PLA2G4B, PLA2G4B, SPTBN5, RNA5SP393, MIR4310.
- chr15:77,894,684–77,904,674, 1 gene: CSPG4P13.
- chr15:85,272,527–85,272,974, 1 gene (within-gene range 0–2): AC044860.3.
- chr16:3,144,015–3,149,963, 1 gene: CASP16P.
- chr17:82,047,902–82,065,887, 3 genes: RFNG, GPS1, DUS1L.
- chr21:45,981,769–46,005,050, 1 gene: COL6A1.
- chr22:22,639,177–22,647,903, 2 genes: POM121L1P, GGTLC2.
- chr22:43,400,331–43,409,681, 1 gene: LINC01639.
- chr22:50,205,585–50,209,542, 2 genes (within-gene range 0–1): AL022328.1, AL022328.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:49,768,130–49,786,385, 1 gene, copy number 5 (within-gene range 2–5): KLHDC2.
- chr21:43,461,960–43,479,534, 2 genes, copy number 11–13: LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 755. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
